Somatic mutation profile of tumor specimen TCGA-D1-A16Y-01A (aliquot TCGA-D1-A16Y-01A-31D-A12J-09) from TCGA case TCGA-D1-A16Y, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 56.0 years (20,455 days).
Specimen TCGA-D1-A16Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b70ae68c-e376-4b05-b100-c112a98c0a81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A16Y-10A (Blood Derived Normal), aliquot TCGA-D1-A16Y-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3488053f-01a5-4ab3-b01d-22d5286c7017

The open-access MAF lists 1,231 somatic variants for this specimen: 976 protein-altering or splice-affecting, 232 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 840, Silent 232, Nonsense Mutation 115, Splice Site 12, Intron 11, RNA 7, Splice Region 6, 5'UTR 3, 3'UTR 2, Frame Shift Ins 2, Nonstop Mutation 1.

Variants (750 of 1,231; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 60/113 reads (53%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 84/173 reads (49%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1972C>T p.R658* (on ENST00000281708 / NM_001349798.2; = p.R578* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 137/299 reads (46%) | hotspot (GDC flag); catalogued as COSV55892162, COSV55908751; called by muse, mutect2, varscan2
- FUBP1 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 146/326 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408536007, COSV53927182; called by muse, mutect2, varscan2
- GLDN | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as rs539703340, COSV59090127; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HGD | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs369517993, CM001711, COSV52196593; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 98/242 reads (40%) | hotspot (GDC flag); catalogued as rs878853865, CM000780, COSV62194747; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 64/169 reads (38%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLE | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519945, COSV57676103, COSV57677068, COSV57683938; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.259C>T p.Q87* | Nonsense Mutation (SNP) | VAF 112/276 reads (41%) | catalogued as rs1554898053, CM981668, COSV64289438; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 112/236 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- RASA1 | c.2365C>T p.R789* | Nonsense Mutation (SNP) | VAF 61/127 reads (48%) | catalogued as rs1463885690, CM083070, COSV57192389; ClinVar: pathogenic; called by mutect2, varscan2
- RB1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 139/335 reads (41%) | catalogued as rs121913296, CM961221, COSV57300832; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SH3TC2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80338923, COSV100101940; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- SMARCD1 | c.548G>T p.R183L | Missense Mutation (SNP) | VAF 58/102 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57317934, COSV57318902; called by muse, mutect2, varscan2
- TP53 | c.721T>C p.S241P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520002, CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 82/191 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: drug response / pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASDH | c.3052T>C p.S1018P | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as COSV52706602; called by muse, mutect2, varscan2
- ABCA1 | c.5563G>A p.A1855T | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs766712712, COSV66066526; called by muse, mutect2, varscan2
- ABCA10 | c.2003A>C p.K668T | Missense Mutation (SNP) | VAF 145/328 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV52220037; called by muse, mutect2, varscan2
- ABCA12 | c.2974G>A p.A992T (on ENST00000272895 / NM_173076.3; = p.A674T on NM_015657.3) | Missense Mutation (SNP) | VAF 110/205 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as COSV55959675; called by muse, mutect2, varscan2
- ABCA5 | c.993A>C p.E331D | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.551); catalogued as COSV67016910; called by muse, mutect2, varscan2
- ABCC2 | c.4045A>G p.R1349G | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64986255; called by muse, mutect2, varscan2
- ABCC4 | c.2639G>A p.R880Q | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.496); catalogued as rs201390689, COSV65312834; called by muse, mutect2, varscan2
- ABCC4 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 98/253 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV65312842; called by muse, mutect2, varscan2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs749786076, COSV53966945; called by muse, mutect2, varscan2
- ABCF2 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 80/180 reads (44%) | catalogued as rs749440754, COSV55181538; called by muse, varscan2
- ABCG5 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53209371, COSV53209690; called by muse, mutect2, varscan2
- ABCG8 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 7/11 reads (64%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.247); catalogued as COSV53210842; called by muse, mutect2, varscan2
- ABHD6 | c.29T>C p.V10A | Missense Mutation (SNP) | VAF 83/182 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55908663; called by muse, mutect2, varscan2
- ABLIM3 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs762942384, COSV58643417; called by muse, mutect2, varscan2
- AC100868.1 | c.1127C>A p.S376Y | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV51842958; called by muse, mutect2, varscan2
- ACAP1 | c.1729C>T p.R577* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs1364336849, COSV50136047; called by muse, mutect2, varscan2
- ACO2 | c.455A>C p.N152T | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53442870; called by muse, mutect2, varscan2
- ACSL6 | c.233G>A p.G78D (on ENST00000379240; = p.G103D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV57298650; called by muse, mutect2, varscan2
- ACTRT1 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 82/168 reads (49%) | catalogued as COSV64419387; called by muse, varscan2
- ACVR1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as rs766547414, COSV55119066; called by muse, mutect2, varscan2
- ADAD1 | c.454T>C p.S152P | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.772); catalogued as COSV56643549; called by muse, mutect2, varscan2
- ADAMTS1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV53170410; called by muse, mutect2, varscan2
- ADAMTS13 | c.4213T>C p.Y1405H | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52469984; called by muse, mutect2, varscan2
- ADAMTS16 | c.236T>G p.I79S | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV56989932; called by muse, mutect2, varscan2
- ADAMTS20 | c.5598G>T p.W1866C | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67131653; called by muse, mutect2, varscan2
- ADCY10 | c.4162T>G p.Y1388D | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63240931; called by muse, mutect2, varscan2
- ADCY10 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63240936; called by muse, mutect2, varscan2
- ADGRA3 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1165791849, COSV51563231; called by muse, mutect2, varscan2
- ADGRB3 | c.441A>C p.E147D | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV65395900; called by muse, mutect2, varscan2
- ADH6 | c.964+2T>C p.X322_splice | Splice Site (SNP) | VAF 109/232 reads (47%) | catalogued as COSV52956180; called by muse, mutect2, varscan2
- ADORA1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374201654, COSV55144405; called by muse, mutect2, varscan2
- AGBL1 | c.1294A>C p.K432Q | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV66858610; called by muse, mutect2, varscan2
- AGBL1 | c.2891C>A p.S964Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66858612; called by muse, mutect2, varscan2
- AGFG1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 84/187 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV59512040; called by muse, mutect2, varscan2
- AHNAK | c.14632T>G p.L4878V | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.358); catalogued as COSV57213775; called by muse, mutect2, varscan2
- AHRR | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs769607059, COSV57086282; called by muse, mutect2, varscan2
- AK5 | c.407T>G p.L136R (on ENST00000354567 / NM_174858.3; = p.L110R on NM_012093.4) | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58355811; called by muse, mutect2, varscan2
- AK9 | c.5576A>C p.K1859T | Missense Mutation (SNP) | VAF 98/203 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV69851325; called by muse, mutect2, varscan2
- AKAP4 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62073830; called by muse, mutect2
- AKNAD1 | c.1434G>T p.E478D | Missense Mutation (SNP) | VAF 140/373 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV62198613; called by muse, mutect2, varscan2
- AL136295.1 | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.073); catalogued as rs375509793; called by muse, mutect2, varscan2
- AL136295.1 | c.171G>T p.K57N | Missense Mutation (SNP) | VAF 201/482 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as COSV55303212; called by muse, mutect2, varscan2
- ALOX12B | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs775449310, COSV59872873; called by muse, mutect2, varscan2
- ALPL | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66375990, COSV66376187; called by muse, mutect2
- ANGPT2 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV57337044; called by muse, mutect2, varscan2
- ANKRD26 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 157/353 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs540155602, COSV65774487; called by muse, mutect2, varscan2
- ANKRD28 | c.2204T>G p.L735R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67518113; called by muse, varscan2
- ANKRD28 | c.2143C>T p.R715W | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs202220330; called by muse, varscan2
- ANO6 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 158/375 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs747156509, COSV100263073; called by muse, mutect2
- ARHGAP35 | c.2989C>T p.R997* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV68329150; called by muse, mutect2, varscan2
- ARHGEF5 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 130/474 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs758237036, COSV50209018; called by muse, mutect2, varscan2
- ARID4B | c.2543A>C p.N848T | Missense Mutation (SNP) | VAF 183/402 reads (46%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV51603326; called by muse, varscan2
- ARID4B | c.2441A>C p.K814T | Missense Mutation (SNP) | VAF 192/434 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as rs759775660, COSV51603342; called by muse, varscan2
- ARMC12 | c.466G>A p.E156K (on ENST00000373866 / NM_001286574.2; = p.E183K on NM_145028.5) | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.056); catalogued as rs148096096; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.1529T>C p.F510S | Missense Mutation (SNP) | VAF 97/197 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63437952; called by muse, mutect2, varscan2
- ARSF | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV63839639; called by muse, mutect2, varscan2
- ASB15 | c.1723T>G p.F575V | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV51925923; called by muse, mutect2, varscan2
- ASB9 | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV66851750; called by muse, mutect2, varscan2
- ASCC2 | c.737T>G p.V246G | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); catalogued as COSV57073811; called by muse, mutect2, varscan2
- ASNS | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 83/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51551950; called by muse, mutect2, varscan2
- ATF7IP | c.2710C>T p.R904* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as rs1283765821, COSV53765658; called by muse, mutect2, varscan2
- ATF7IP | c.3292C>T p.R1098* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as rs770191292, COSV53770969; called by muse, mutect2, varscan2
- ATG2B | c.4957C>T p.R1653C | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs773625847, COSV55890358; called by muse, mutect2, varscan2
- ATG4C | c.676A>G p.K226E | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58605611; called by muse, mutect2, varscan2
- ATM | c.8054C>A p.S2685* | Nonsense Mutation (SNP) | VAF 85/199 reads (43%) | catalogued as COSV53744642, COSV53753951; called by muse, mutect2, varscan2
- ATP1B3 | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 67/185 reads (36%) | catalogued as COSV53949812; called by muse, mutect2, varscan2
- ATP4B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs139992135, COSV58928819; called by muse, mutect2, varscan2
- ATP5ME | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 74/510 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as COSV55326517; called by muse, mutect2, varscan2
- ATRX | c.6305T>G p.F2102C | Missense Mutation (SNP) | VAF 165/357 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64876723; called by muse, mutect2, varscan2
- AXDND1 | c.1784T>G p.I595R | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV62642752; called by muse, mutect2, varscan2
- BACH1 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750785692, COSV54518596; called by muse, mutect2, varscan2
- BAZ1A | c.4438C>T p.R1480C | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV62409067, COSV62409929; called by muse, mutect2, varscan2
- BIRC6 | c.5167G>A p.E1723K | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.706); catalogued as rs776666613, COSV70199361; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1400329743, COSV63244190, COSV63244592; called by muse, mutect2, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 79/151 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMERB1 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as rs139998961; called by muse, mutect2, varscan2
- BMP10 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV54895307; called by muse, mutect2, varscan2
- BMP2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs776834114, COSV66577307; called by muse, mutect2
- BMP6 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs200811682; called by muse, mutect2, varscan2
- BMT2 | c.709C>T p.L237F | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.714); catalogued as COSV51776823; called by muse, mutect2, varscan2
- BMX | c.1723C>A p.P575T | Missense Mutation (SNP) | VAF 131/309 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751005076, COSV59591397; called by muse, mutect2, varscan2
- BNC1 | c.2470A>G p.T824A | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV61757443; called by muse, mutect2, varscan2
- BPIFB6 | c.823C>A p.H275N | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV62755242; called by muse, mutect2, varscan2
- BRD1 | c.2911G>A p.V971M (on ENST00000216267 / NM_001349940.1; = p.V1102M on NM_001304808.3) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53457468; called by muse, mutect2, varscan2
- BROX | c.924C>A p.F308L | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV61799275; called by muse, mutect2, varscan2
- BRWD3 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV100955816, COSV64748283; called by muse, mutect2, varscan2
- BTBD9 | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 59/133 reads (44%) | catalogued as COSV58426119; called by muse, mutect2, varscan2
- C1QC | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65889277; called by muse, mutect2
- C1orf94 | c.1687G>A p.D563N (on ENST00000488417 / NM_001134734.2; = p.D373N on NM_032884.5) | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64914016; called by muse, mutect2, varscan2
- C20orf194 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 187/385 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs376611860; called by muse, mutect2, varscan2
- C20orf96 | c.1021C>T p.R341W (on ENST00000360321 / NM_153269.3; = p.R340W on NM_080571.1) | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1246943904, COSV64403404; called by muse, mutect2, varscan2
- C2orf76 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs374956671; called by muse, mutect2, varscan2
- C3orf22 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs762729878, COSV59072815; called by muse, mutect2, varscan2
- C3orf38 | c.317A>C p.K106T | Missense Mutation (SNP) | VAF 80/175 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0.051); catalogued as COSV59628025; called by muse, mutect2, varscan2
- C5AR2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs375745726; called by muse, mutect2, varscan2
- C7orf25 | c.144C>A p.F48L | Missense Mutation (SNP) | VAF 98/245 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV63273701; called by muse, mutect2, varscan2
- C8orf34 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 206/479 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs771361055, COSV57397940; called by muse, mutect2, varscan2
- C9orf131 | c.587T>G p.F196C | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769884755, COSV56611327; called by muse, mutect2, varscan2
- C9orf43 | c.499C>A p.L167M | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); catalogued as COSV55912675, COSV99928351; called by muse, mutect2, varscan2
- CACNA1E | c.260A>G p.D87G | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV62395221; called by muse, mutect2, varscan2
- CACNA1I | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.33); catalogued as rs746228837, COSV60801784; called by muse, mutect2
- CACNB4 | c.1384T>G p.Y462D | Missense Mutation (SNP) | VAF 102/226 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.143); catalogued as COSV52394006; called by muse, mutect2, varscan2
- CACNG5 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752101967, COSV50055815; called by muse, mutect2, varscan2
- CADPS | c.2677C>A p.L893I | Missense Mutation (SNP) | VAF 115/214 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as rs1229955756, COSV51880369; called by muse, mutect2, varscan2
- CADPS | c.1976G>T p.R659I | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99339151; called by muse, mutect2
- CADPS2 | c.2269A>C p.N757H | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.924); catalogued as COSV57363952; called by muse, mutect2, varscan2
- CALHM6 | c.717T>G p.C239W | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV63991576; called by muse, mutect2, varscan2
- CAPRIN2 | c.896A>C p.K299T | Missense Mutation (SNP) | VAF 136/331 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51832570; called by muse, mutect2, varscan2
- CASP10 | c.1123C>T p.R375W (on ENST00000272879 / NM_032974.5; = p.R332W on NM_001230.5) | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53778139; called by muse, mutect2, varscan2
- CASP4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 162/363 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1030418546, COSV67744181, COSV67744639; called by muse, mutect2, varscan2
- CASP5 | c.1217C>A p.S406* | Nonsense Mutation (SNP) | VAF 134/315 reads (43%) | catalogued as rs549693625, COSV52828605; called by muse, mutect2, varscan2
- CAVIN2 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV58424034; called by muse, mutect2, varscan2
- CBLN4 | c.311A>T p.N104I | Missense Mutation (SNP) | VAF 122/263 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV50352257; called by muse, mutect2, varscan2
- CC2D2B | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 95/186 reads (51%) | catalogued as COSV100729485; called by muse, mutect2, varscan2
- CCDC110 | c.2035G>T p.E679* | Nonsense Mutation (SNP) | VAF 106/235 reads (45%) | catalogued as COSV100293924, COSV56870269; called by muse, mutect2, varscan2
- CCDC112 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 260/599 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV65473212; called by muse, mutect2, varscan2
- CCDC138 | c.1866T>G p.I622M | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54567200; called by muse, mutect2, varscan2
- CCDC42 | c.142A>C p.K48Q | Missense Mutation (SNP) | VAF 131/302 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV53448766; called by muse, mutect2, varscan2
- CCDC82 | c.968A>C p.K323T | Missense Mutation (SNP) | VAF 191/425 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as COSV53593496; called by muse, mutect2, varscan2
- CCDC83 | c.1232C>A p.S411Y (on ENST00000342404 / NM_001286159.2; = p.S442Y on NM_173556.5) | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs767082436, COSV54701866; called by muse, mutect2, varscan2
- CCNE2 | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 100/226 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as rs753297056, COSV57376080; called by muse, mutect2, varscan2
- CCNQ | c.174C>A p.F58L | Missense Mutation (SNP) | VAF 94/195 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52344400; called by muse, mutect2, varscan2
- CCNT2 | c.1342C>A p.L448I | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV99750820; called by muse, mutect2
- CCT6B | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 144/285 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.7); catalogued as rs755333614, COSV58487981; called by muse, mutect2, varscan2
- CCZ1 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 197/514 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV58074036; called by muse, mutect2, varscan2
- CD1A | c.173A>G p.D58G | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.192); catalogued as rs764062414, COSV56861839; called by muse, mutect2, varscan2
- CD300E | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60790545, COSV60791875; called by muse, mutect2, varscan2
- CD36 | c.1373C>A p.A458D | Missense Mutation (SNP) | VAF 151/351 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as rs866158583, COSV59213125; called by muse, mutect2, varscan2
- CD83 | c.408G>T p.E136D | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100997807; called by muse, mutect2
- CDAN1 | c.2578C>A p.P860T | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV62332047; called by muse, mutect2, varscan2
- CDH10 | c.1025G>T p.R342I | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100053606, COSV52581098; called by muse, mutect2, varscan2
- CDH19 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs754638138, COSV50958036; called by muse, mutect2, varscan2
- CDH20 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53009981; called by muse, mutect2, varscan2
- CDK17 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 112/279 reads (40%) | catalogued as COSV54127319, COSV99703093; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4208G>A p.R1403Q | Missense Mutation (SNP) | VAF 82/207 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767034315, COSV62574308; called by muse, mutect2, varscan2
- CDKL3 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 92/197 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54741588; called by muse, mutect2, varscan2
- CDKL3 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 117/250 reads (47%) | catalogued as COSV54740945; called by muse, mutect2, varscan2
- CDS1 | c.1322T>C p.I441T | Missense Mutation (SNP) | VAF 67/170 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV55688088; called by muse, mutect2, varscan2
- CELF4 | c.1332C>T p.F444= | Splice Region (SNP) | VAF 16/33 reads (48%) | catalogued as rs1419294006, COSV58445367; called by muse, mutect2, varscan2
- CEP290 | c.693A>C p.K231N | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV58351887; called by muse, mutect2, varscan2
- CEP44 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 84/186 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs769157129, COSV56658367; called by muse, mutect2, varscan2
- CES1 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV62086978; called by muse, mutect2, varscan2
- CES1 | c.248A>G p.Y83C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62086985; called by muse, mutect2, varscan2
- CFAP45 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as rs200252683, COSV63647949; called by muse, mutect2, varscan2
- CFAP52 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV60491207; called by muse, mutect2, varscan2
- CFAP74 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as rs917431326, COSV54564663; called by muse, mutect2, varscan2
- CFAP97 | c.1396C>T p.R466C | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991297380, COSV101515137; called by muse, mutect2
- CFL2 | c.22A>C p.N8H | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV53311557; called by muse, mutect2, varscan2
- CFP | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs762231424, COSV55950326; called by muse, mutect2, varscan2
- CHAF1B | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.53); catalogued as COSV58440118, COSV58441757; called by muse, mutect2, varscan2
- CHD1L | c.1027A>G p.T343A | Missense Mutation (SNP) | VAF 144/310 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV63613981; called by muse, mutect2, varscan2
- CHD2 | c.3640G>A p.G1214R | Missense Mutation (SNP) | VAF 103/205 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV67709490; called by muse, mutect2, varscan2
- CHD8 | c.3236C>T p.T1079I (on ENST00000646647 / NM_001170629.2; = p.T800I on NM_020920.4) | Missense Mutation (SNP) | VAF 73/165 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV67870560; called by muse, mutect2, varscan2
- CHL1 | c.1804G>A p.D602N (on ENST00000397491 / NM_001253387.1; = p.D618N on NM_006614.4) | Missense Mutation (SNP) | VAF 113/225 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as rs186218301; called by muse, mutect2, varscan2
- CHST9 | c.880T>G p.F294V | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52437339; called by muse, mutect2, varscan2
- CKAP2 | c.86A>C p.K29T | Missense Mutation (SNP) | VAF 89/210 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV51622146; called by muse, mutect2, varscan2
- CKAP5 | c.3662A>G p.N1221S | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV56367851; called by muse, mutect2, varscan2
- CLCA4 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.232); catalogued as rs764538668, COSV55368292, COSV99760242; called by muse, mutect2, varscan2
- CLCN4 | c.1012C>G p.L338V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.817); catalogued as COSV66466561; called by muse, mutect2, varscan2
- CLEC4F | c.1438T>G p.L480V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV55479411; called by muse, mutect2, varscan2
- CLEC6A | c.488T>G p.F163C | Missense Mutation (SNP) | VAF 121/278 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV65987173; called by muse, mutect2, varscan2
- CLPB | c.479T>C p.V160A | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV53629894; called by muse, mutect2, varscan2
- CLTCL1 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 51/91 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV54230771; called by muse, mutect2, varscan2
- CMIP | c.1676A>C p.K559T (on ENST00000537098 / NM_198390.2; = p.K465T on NM_030629.3) | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV67698365; called by muse, mutect2, varscan2
- CMTM5 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100198085; called by muse, mutect2, varscan2
- CNTN1 | c.403C>A p.L135I | Missense Mutation (SNP) | VAF 81/149 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as COSV61639710; called by muse, mutect2, varscan2
- CNTN4 | c.15G>A p.W5* | Nonsense Mutation (SNP) | VAF 101/225 reads (45%) | catalogued as COSV68573529; called by muse, mutect2, varscan2
- CNTN6 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs774492055, COSV63172416; called by muse, mutect2, varscan2
- CNTNAP4 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 104/199 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs556620057, COSV56680869; called by muse, mutect2, varscan2
- CNTNAP5 | c.3361C>T p.R1121* | Nonsense Mutation (SNP) | VAF 43/116 reads (37%) | catalogued as COSV70486368; called by muse, mutect2, varscan2
- CNTRL | c.2745A>C p.E915D | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV53047145; called by muse, mutect2, varscan2
- COCH | c.960C>A p.F320L (on ENST00000216361 / NM_001347720.1; = p.F255L on NM_004086.3) | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99363710; called by muse, mutect2
- COG6 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs762985352, COSV62996000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL16A1 | c.3695C>A p.P1232H | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV54706010; called by muse, mutect2, varscan2
- COL16A1 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54706027; called by muse, mutect2, varscan2
- COL4A3 | c.134A>G p.K45R | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV67415652; called by muse, mutect2, varscan2
- COL4A3 | c.4664C>T p.A1555V | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs369575989; called by muse, mutect2, varscan2
- COL9A1 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 9/200 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.143); catalogued as COSV100294997; called by muse, mutect2
- COPS2 | c.773T>G p.F258C | Missense Mutation (SNP) | VAF 121/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54645291; called by muse, mutect2, varscan2
- COX5A | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs200811470, COSV59279457; called by muse, mutect2, varscan2
- CREB3L3 | c.1228A>C p.N410H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV50196639; called by muse, mutect2, varscan2
- CRYBG3 | c.8107C>T p.R2703* | Nonsense Mutation (SNP) | VAF 130/296 reads (44%) | catalogued as rs945316099, COSV51709405; called by muse, mutect2, varscan2
- CSMD1 | c.8932T>C p.S2978P (on ENST00000520002; = p.S2977P on NM_033225.6) | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.958); catalogued as COSV59300753; called by muse, mutect2, varscan2
- CSMD3 | c.7987C>T p.R2663* (on ENST00000297405 / NM_001363185.1; = p.R2559* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 74/140 reads (53%) | catalogued as rs1432657584, COSV52100177, COSV52156018; called by muse, mutect2, varscan2
- CSMD3 | c.2498A>C p.E833A (on ENST00000297405 / NM_001363185.1; = p.E729A on NM_052900.3) | Missense Mutation (SNP) | VAF 72/152 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52183802; called by muse, mutect2, varscan2
- CSMD3 | c.1661G>A p.G554E (on ENST00000297405 / NM_001363185.1; = p.G450E on NM_052900.3) | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.933); catalogued as rs1361326399, COSV52183814; called by muse, mutect2, varscan2
- CSPP1 | c.1003G>T p.E335* (on ENST00000676605; = p.E294* on NM_024790.6) | Nonsense Mutation (SNP) | VAF 30/61 reads (49%) | catalogued as rs1563541637, COSV51584584; called by muse, mutect2, varscan2
- CST2 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.973); catalogued as rs372139444, COSV59031682; called by muse, mutect2, varscan2
- CTCFL | c.763G>T p.G255* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV54774441; called by muse, mutect2, varscan2
- CTNNB1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1245266458, COSV62695900; called by muse, mutect2, varscan2
- CTSG | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs201990007, COSV53535508; called by muse, mutect2, varscan2
- CTSL | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV58246142; called by muse, mutect2, varscan2
- CUL4A | c.1295C>T p.T432M (on ENST00000375440 / NM_001008895.4; = p.T332M on NM_003589.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs752132240, COSV58372954; called by muse, mutect2, varscan2
- CUL4B | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 275/647 reads (43%) | SIFT tolerated (0.87); PolyPhen benign (0.013); catalogued as COSV60687477; called by muse, mutect2, varscan2
- CUX1 | c.622C>T p.R208* (on ENST00000292535 / NM_181552.4; = p.R219* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | catalogued as rs782288993, COSV52891789; called by muse, mutect2, varscan2
- CXADR | c.123C>A p.C41* | Nonsense Mutation (SNP) | VAF 45/102 reads (44%) | catalogued as COSV53029081; called by muse, mutect2, varscan2
- CXorf66 | c.810G>T p.K270N | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV65169255; called by muse, mutect2, varscan2
- CYBB | c.1642A>C p.K548Q | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as CM106295, COSV66085401; called by muse, mutect2, varscan2
- CYLD | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772603046, COSV61094734; called by muse, mutect2, varscan2
- CYP21A2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.253); catalogued as COSV64479051; called by muse, mutect2, varscan2
- CYP26A1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 104/234 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771199176, COSV56418256; called by muse, mutect2, varscan2
- CYP26A1 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 45/74 reads (61%) | catalogued as rs1222360754, COSV56418267; called by muse, mutect2, varscan2
- CYSLTR1 | c.584T>G p.F195C | Missense Mutation (SNP) | VAF 89/191 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV64820178; called by muse, mutect2, varscan2
- DACH2 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64167864; called by muse, mutect2, varscan2
- DCAF4L1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1224359974, COSV60787139; called by muse, mutect2, varscan2
- DCC | c.1807C>T p.R603C | Missense Mutation (SNP) | VAF 150/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs267605206, COSV59087112; called by muse, mutect2, varscan2
- DCDC1 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 99/236 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV60842629, COSV60862780; called by muse, mutect2, varscan2
- DCLK2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 242/518 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.398); catalogued as COSV56198611; called by muse, mutect2, varscan2
- DCP2 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 105/251 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as COSV66616989; called by muse, mutect2, varscan2
- DDB2 | c.965G>T p.C322F | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1237996732, COSV57038661; called by muse, mutect2, varscan2
- DDR2 | c.1865T>A p.F622Y | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63371078; called by muse, mutect2, varscan2
- DDX4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs757458025, COSV61753971, COSV61754925; called by muse, mutect2, varscan2
- DDX53 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.055); catalogued as COSV60069046; called by muse, mutect2, varscan2
- DEFB125 | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV66703294; called by muse, mutect2, varscan2
- DENND4A | c.357T>G p.I119M | Missense Mutation (SNP) | VAF 10/143 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV101475373; called by muse, mutect2
- DEPDC1B | c.1582C>T p.R528* | Nonsense Mutation (SNP) | VAF 159/370 reads (43%) | catalogued as rs575323127, COSV54009042; called by muse, mutect2, varscan2
- DEPTOR | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 92/206 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.166); catalogued as rs747255387, COSV53815986; called by muse, mutect2, varscan2
- DEUP1 | c.1306T>G p.L436V | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as COSV53212356; called by muse, mutect2, varscan2
- DGKB | c.2030C>A p.S677Y | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV51783265; called by muse, mutect2, varscan2
- DHX38 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as rs368707127; called by muse, mutect2, varscan2
- DIAPH2 | c.3218G>A p.R1073Q | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs963211561, COSV61270265; called by muse, mutect2, varscan2
- DLG2 | c.49C>T p.R17* | Nonsense Mutation (SNP) | VAF 65/181 reads (36%) | catalogued as COSV65841014; called by muse, mutect2, varscan2
- DMAC2L | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 118/266 reads (44%) | catalogued as rs748784549, COSV55413384; called by muse, mutect2, varscan2
- DMAP1 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1012570208, COSV60000695; called by muse, mutect2, varscan2
- DMD | c.3640G>T p.V1214L | Missense Mutation (SNP) | VAF 129/292 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs866934800, COSV63755956; called by muse, mutect2, varscan2
- DMD | c.3158T>A p.I1053N | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.248); catalogued as COSV100820533; called by muse, mutect2, varscan2
- DNAH12 | c.188G>T p.R63I | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV60857036; called by muse, mutect2, varscan2
- DNAH5 | c.4361G>A p.R1454Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs542708170, CM020271, COSV54215668; ClinVar: uncertain significance; called by muse, mutect2
- DNAH7 | c.5507G>T p.R1836I | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56765300; called by muse, mutect2, varscan2
- DNAH7 | c.2474A>C p.K825T | Missense Mutation (SNP) | VAF 108/220 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV56765314; called by muse, mutect2, varscan2
- DNAJC13 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 185/394 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV53449252; called by muse, mutect2, varscan2
- DNAJC5G | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 99/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV56080020; called by muse, mutect2, varscan2
- DOCK1 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as COSV54731922; called by muse, mutect2, varscan2
- DPYSL2 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs762997682, COSV60783425; called by muse, mutect2, varscan2
- DSCAML1 | c.4924G>T p.A1642S (on ENST00000321322; = p.A1582S on NM_020693.4) | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.863); catalogued as COSV58390856; called by muse, mutect2, varscan2
- DSEL | c.2144C>A p.S715Y | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.998); catalogued as COSV59491585; called by muse, mutect2, varscan2
- DSEL | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59491595; called by muse, mutect2, varscan2
- DSP | c.7473A>C p.E2491D | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV65792816; called by muse, mutect2, varscan2
- DST | c.19153G>A p.E6385K (on ENST00000361203 / NM_001374722.1; = p.E4082K on NM_015548.5) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs376734906; called by muse, mutect2, varscan2
- DTX3L | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755071547, COSV56144163; called by muse, mutect2, varscan2
- DYNC1I1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV61460913; called by muse, mutect2, varscan2
- DYNC2H1 | c.4283G>T p.R1428I | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62090943; called by muse, mutect2, varscan2
- DYNC2H1 | c.10714G>A p.A3572T | Missense Mutation (SNP) | VAF 122/200 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as rs1473012975, COSV62094396; called by muse, varscan2
- DYNC2H1 | c.11975A>C p.K3992T | Missense Mutation (SNP) | VAF 76/162 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV62094402; called by muse, mutect2, varscan2
- DZIP1 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 155/370 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1016275069, COSV61265858; called by muse, mutect2, varscan2
- EEF1A2 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as COSV53206145; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1358C>T p.A453V (on ENST00000361735 / NM_015935.5; = p.A367V on NM_014955.3) | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs752973393, COSV62283080; called by muse, mutect2, varscan2
- EFL1 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 100/236 reads (42%) | catalogued as COSV51605634; called by muse, mutect2, varscan2
- EIF2S2 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV66621582; called by muse, mutect2, varscan2
- EIF4EBP2 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs201115758, COSV64667397, COSV64667599; called by muse, mutect2, varscan2
- ELAPOR2 | c.2897C>T p.T966M (on ENST00000450689 / NM_001142749.3; = p.T799M on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 65/167 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199613938, COSV51886971; called by muse, mutect2, varscan2
- ELAPOR2 | c.2725A>C p.K909Q (on ENST00000450689 / NM_001142749.3; = p.K742Q on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.271); catalogued as COSV51883873, COSV51886981; called by muse, mutect2, varscan2
- ELF5 | c.610C>T p.R204W (on ENST00000312319 / NM_198381.2; = p.R194W on NM_001422.4) | Missense Mutation (SNP) | VAF 132/325 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs759245139, COSV56629071; called by muse, mutect2, varscan2
- ELMO1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs776563605, COSV60299281; called by muse, mutect2, varscan2
- ELMO3 | c.571G>A p.D191N (on ENST00000652269; = p.D138N on NM_024712.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.216); catalogued as rs201641837; called by muse, mutect2, varscan2
- ELOVL2 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV61155251; called by muse, mutect2, varscan2
- ELP2 | c.2348G>A p.R783K | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60851105; called by muse, mutect2, varscan2
- EPG5 | c.4480G>T p.E1494* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV56350015; called by muse, mutect2, varscan2
- EPHX4 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 83/187 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.015); catalogued as rs201582889; called by muse, mutect2, varscan2
- EPM2AIP1 | c.649C>A p.H217N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.304); catalogued as COSV51618142; called by muse, mutect2, varscan2
- EPS15L1 | c.2106C>T p.L702= | Splice Region (SNP) | VAF 104/259 reads (40%) | catalogued as rs780173380, COSV50168886; called by muse, mutect2, varscan2
- ERBB3 | c.3647C>T p.S1216F | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs1281265231, COSV57253584; called by muse, mutect2, varscan2
- ERCC5 | c.507G>T p.M169I | Missense Mutation (SNP) | VAF 158/422 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV63244500, COSV63245122; called by muse, mutect2, varscan2
- ERCC6 | c.3662G>A p.R1221Q | Missense Mutation (SNP) | VAF 210/449 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs200431100, COSV63389936; called by muse, mutect2, varscan2
- ERICH3 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 97/218 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs951721145, COSV100444840, COSV58606832; called by muse, mutect2, varscan2
- ERICH5 | c.779G>T p.R260I | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV59314961, COSV59315806; called by muse, mutect2, varscan2
- ERICH6 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 135/305 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.786); catalogued as COSV55800439; called by muse, mutect2, varscan2
- ERMN | c.821G>T p.R274I | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68075280, COSV68075322; called by muse, mutect2
- ESYT2 | c.1135C>T p.R379W (on ENST00000613624; = p.R303W on NM_020728.3) | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772699152, COSV51747637; called by muse, mutect2, varscan2
- ETS2 | c.852C>G p.D284E | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV62872966; called by muse, mutect2, varscan2
- EXOC1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs746493906, COSV62119089, COSV99051309; called by muse, mutect2, varscan2
- EXOC4 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs772062658, COSV54095146; called by muse, mutect2, varscan2
- EXT2 | c.1987C>A p.L663I (on ENST00000343631; = p.L696I on NM_000401.3) | Missense Mutation (SNP) | VAF 57/122 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV59150120; called by muse, mutect2, varscan2
- EYS | c.837T>G p.I279M | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.782); catalogued as COSV60985830; called by muse, mutect2, varscan2
- F13A1 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs761188694, COSV53555015; called by muse, mutect2, varscan2
- F7 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs764807079, CM001149, COSV60644962; called by muse, mutect2, varscan2
- F8 | c.3660G>T p.K1220N | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as COSV64273578; called by muse, varscan2
- FAF2 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs371906699, COSV56131033; called by muse, mutect2, varscan2
- FAM114A2 | c.940A>C p.T314P | Missense Mutation (SNP) | VAF 79/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61077891; called by muse, mutect2, varscan2
- FAM126A | c.1183G>T p.E395* | Nonsense Mutation (SNP) | VAF 64/141 reads (45%) | catalogued as rs774309128, COSV69471752; called by muse, mutect2, varscan2
- FAM135B | c.4202G>A p.G1401E | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52720142, COSV52748115; called by muse, mutect2, varscan2
- FAM172A | c.719G>A p.R240Q | Missense Mutation (SNP) | VAF 217/495 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.062); catalogued as rs770845342, COSV67937546; called by muse, mutect2, varscan2
- FAM200A | c.134C>A p.S45* | Nonsense Mutation (SNP) | VAF 15/371 reads (4%) | catalogued as COSV101282732; called by muse, mutect2
- FAM209B | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.96); catalogued as rs374650237; called by muse, mutect2, varscan2
- FAM83G | c.586G>A p.G196S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.752); catalogued as rs200439128; called by muse, mutect2, varscan2
- FANCB | c.636T>G p.F212L | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV60759939; called by muse, mutect2, varscan2
- FASTKD5 | c.2120A>G p.Y707C | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369345081, COSV53906177; called by muse, mutect2, varscan2
- FAT4 | c.9072C>A p.F3024L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV100626806, COSV58685855, COSV58694585; called by muse, mutect2, varscan2
- FBN1 | c.6397G>T p.E2133* | Nonsense Mutation (SNP) | VAF 76/145 reads (52%) | catalogued as CM154852, COSV57312439; called by muse, mutect2, varscan2
- FBXL3 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 55/111 reads (50%) | catalogued as COSV100842332, COSV62918562; called by muse, mutect2, varscan2
- FBXW7 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 77/168 reads (46%) | catalogued as rs781123562, COSV55916781; called by muse, mutect2, varscan2
- FER | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 46/129 reads (36%) | catalogued as COSV55287737; called by muse, mutect2, varscan2
- FGFR1OP2 | c.584A>G p.Q195R | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs774242496, COSV57587113; called by muse, mutect2, varscan2
- FIS1 | c.421G>A p.G141R | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs997985356, COSV99778947; called by muse, mutect2, varscan2
- FLACC1 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.533); catalogued as rs142904738; called by muse, mutect2, varscan2
- FLG | c.11603A>G p.D3868G | Missense Mutation (SNP) | VAF 99/211 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs745787051, COSV64241940; called by muse, mutect2, varscan2
- FLG | c.11026A>G p.T3676A | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.426); catalogued as COSV64241945; called by muse, mutect2, varscan2
- FLRT2 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100420246, COSV58138393; called by muse, mutect2, varscan2
- FMO2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.498); catalogued as rs145420492, COSV52947781; called by muse, mutect2, varscan2
- FMR1 | c.781A>G p.T261A | Missense Mutation (SNP) | VAF 156/350 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV54423969; called by muse, mutect2, varscan2
- FMR1NB | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.842); catalogued as rs782812437, COSV65071889; called by muse, mutect2, varscan2
- FN1 | c.1674C>T p.V558= | Splice Region (SNP) | VAF 73/146 reads (50%) | catalogued as rs774030542, COSV60553030; called by muse, mutect2, varscan2
- FOCAD | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs938415809, COSV58099185; called by muse, mutect2, varscan2
- FOXF1 | c.1031T>G p.F344C | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs760885087, CD093484, COSV52286510; called by muse, mutect2, varscan2
- FOXG1 | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.274); catalogued as COSV57396836; called by muse, mutect2
- FOXP2 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 90/208 reads (43%) | catalogued as COSV63486184, COSV63494364; called by muse, mutect2, varscan2
- FRMD6 | c.965G>A p.R322H (on ENST00000344768 / NM_001267046.2; = p.R314H on NM_152330.4) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1381185536, COSV61088038; called by muse, mutect2, varscan2
- FRMPD2 | c.2286G>T p.R762S | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.2); catalogued as COSV100563744, COSV59718046; called by muse, mutect2, varscan2
- G6PC | c.1062G>T p.K354N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as COSV53831021, COSV53833300; called by muse, mutect2, varscan2
- GAB3 | c.1644+1G>A p.X548_splice | Splice Site (SNP) | VAF 47/123 reads (38%) | catalogued as COSV65819590; called by muse, mutect2, varscan2
- GABRA4 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs770261411, COSV51924008; called by muse, mutect2, varscan2
- GALNT12 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs200303625, COSV66662720; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GALNT15 | c.1805A>C p.K602T | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV60217259; called by muse, mutect2, varscan2
- GALNT17 | c.986C>T p.S329L | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs771622041, COSV61146904; called by muse, mutect2, varscan2
- GALNTL6 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 31/70 reads (44%) | catalogued as rs1237743834, COSV72491030; called by muse, mutect2, varscan2
- GAR1 | c.369+1G>A p.X123_splice | Splice Site (SNP) | VAF 72/151 reads (48%) | catalogued as COSV56993331; called by muse, mutect2, varscan2
- GDPD2 | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 63/146 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs371860180, COSV65532907; called by muse, mutect2, varscan2
- GFRA1 | c.717G>T p.E239D | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62605770; called by muse, mutect2, varscan2
- GFRA1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 139/307 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.54); catalogued as rs368286985; called by muse, mutect2, varscan2
- GINS4 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs775844956, COSV52531514; called by muse, mutect2, varscan2
- GK5 | c.383A>C p.K128T | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as COSV67485763; called by muse, mutect2, varscan2
- GLI3 | c.3490G>A p.E1164K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67887120; called by muse, mutect2, varscan2
- GLI3 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as rs752246768, COSV67888041; called by muse, mutect2, varscan2
- GLRA4 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780471240, COSV65455106; called by muse, mutect2, varscan2
- GNG2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV58916458; called by muse, mutect2, varscan2
- GOLGA4 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 55/109 reads (50%) | catalogued as COSV62710749; called by muse, mutect2, varscan2
- GOLGA4 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1224246676, COSV62710752; called by muse, mutect2, varscan2
- GOLGA4 | c.5852A>C p.K1951T | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62710754; called by muse, mutect2, varscan2
- GP2 | c.1102G>A p.E368K (on ENST00000381362 / NM_001007240.3; = p.E365K on NM_001502.4) | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV56892940; called by muse, mutect2, varscan2
- GPATCH2L | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 82/197 reads (42%) | catalogued as COSV55046641; called by muse, mutect2, varscan2
- GPRASP1 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV64354927; called by muse, mutect2
- GRB10 | c.812A>C p.Q271P | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV60010684; called by muse, mutect2, varscan2
- GRHL2 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV52546692, COSV99307214; called by muse, mutect2
- GRIA2 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as rs368092099; called by muse, mutect2, varscan2
- GRIN2A | c.3475C>T p.R1159C | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV58019525; called by muse, mutect2, varscan2
- GRIN3A | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs974456917, COSV62451266; called by muse, mutect2, varscan2
- GYS1 | c.978C>A p.F326L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV54402874; called by muse, mutect2, varscan2
- GYS2 | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV53923445; called by muse, mutect2, varscan2
- GYS2 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 96/204 reads (47%) | catalogued as COSV53923456, COSV53924924; called by muse, mutect2, varscan2
- H3C8 | c.287C>G p.A96G | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as COSV59953008; called by muse, mutect2, varscan2
- HAUS3 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV54722772; called by muse, mutect2, varscan2
- HDDC3 | c.275A>G p.D92G | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57745997; called by muse, mutect2, varscan2
- HDLBP | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.106); catalogued as COSV60495715; called by muse, mutect2, varscan2
- HEATR5B | c.1616G>A p.R539Q | Missense Mutation (SNP) | VAF 104/236 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as rs1342433299, COSV51850664; called by muse, mutect2, varscan2
- HEATR9 | c.1598C>T p.T533M | Missense Mutation (SNP) | VAF 139/295 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs143722904; called by muse, mutect2, varscan2
- HECTD4 | c.11101C>T p.L3701F | Missense Mutation (SNP) | VAF 76/165 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66392162; called by muse, mutect2, varscan2
- HECW2 | c.3262T>G p.F1088V | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99647628; called by muse, mutect2
- HELLS | c.340A>C p.N114H | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV53297305; called by muse, mutect2, varscan2
- HEPHL1 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747731426, COSV59892080; called by muse, mutect2, varscan2
- HERC6 | c.2212T>C p.Y738H | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52030127; called by muse, mutect2, varscan2
- HGF | c.1386T>G p.D462E | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55949693, COSV55949736; called by muse, mutect2, varscan2
- HINT3 | c.359G>T p.R120I | Missense Mutation (SNP) | VAF 91/220 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV57649615; called by muse, mutect2, varscan2
- HIVEP1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 97/207 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as rs369283883; called by muse, mutect2, varscan2
- HK2 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 129/250 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs763967521, COSV51874863, COSV99309445; called by muse, mutect2, varscan2
- HK3 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.11); catalogued as rs1347019308, COSV52840059; called by muse, mutect2, varscan2
- HMGN1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 52/127 reads (41%) | catalogued as COSV55742500; called by muse, mutect2, varscan2
- HNRNPF | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 17/147 reads (12%) | catalogued as rs760246508, COSV61560579; called by muse, mutect2, varscan2
- HOATZ | c.361C>A p.L121I (on ENST00000375618 / NM_001100388.1; = p.L148I on NM_207430.2) | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.095); catalogued as COSV60441357; called by muse, mutect2, varscan2
- HOOK3 | c.2045A>G p.E682G | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV56882518; called by muse, mutect2, varscan2
- HOXC12 | c.804A>C p.K268N | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54534991; called by muse, mutect2, varscan2
- HOXD3 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV50880640, COSV50880789; called by muse, mutect2, varscan2
- HRG | c.385A>C p.S129R | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.103); catalogued as COSV51645728; called by muse, mutect2, varscan2
- HSF2 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 135/327 reads (41%) | catalogued as COSV63773742, COSV63773915; called by muse, mutect2, varscan2
- HUWE1 | c.6634A>G p.I2212V | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV53345777; called by muse, mutect2, varscan2
- IDS | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as COSV61712429; called by muse, mutect2, varscan2
- IFIT1B | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV65663418; called by muse, mutect2, varscan2
- IFIT2 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV51078819; called by muse, mutect2, varscan2
- IFNG | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 189/392 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV57491293; called by muse, mutect2, varscan2
- IGLV3-25 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs374596533; called by muse, varscan2
- IL12A | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756430989, COSV59758792; called by muse, mutect2, varscan2
- IL12RB1 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs748173451, COSV59097194; called by muse, mutect2, varscan2
- IL12RB2 | c.1649T>G p.M550R | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV52023547; called by muse, mutect2, varscan2
- IL13RA2 | c.925A>G p.R309G | Missense Mutation (SNP) | VAF 335/735 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54565214; called by muse, mutect2, varscan2
- IL31RA | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs748001461, COSV61694232; called by muse, mutect2, varscan2
- IL34 | c.698T>C p.V233A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV99851889; called by muse, mutect2
- IMMP1L | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs746866007, COSV53444315; called by muse, mutect2, varscan2
- INPP5E | c.1834G>T p.E612* | Nonsense Mutation (SNP) | VAF 38/100 reads (38%) | catalogued as COSV65496378; called by muse, mutect2, varscan2
- IQCF2 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 57/132 reads (43%) | catalogued as rs201262177, COSV60761034; called by muse, mutect2, varscan2
- IQGAP2 | c.907+1G>A p.X303_splice | Splice Site (SNP) | VAF 53/122 reads (43%) | catalogued as COSV57173515; called by muse, mutect2, varscan2
- IRS4 | c.2831C>T p.S944L | Missense Mutation (SNP) | VAF 129/261 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs771919696, COSV64533860; called by muse, mutect2, varscan2
- ISLR2 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV62302160; called by muse, mutect2, varscan2
- ITGA11 | c.3498C>T p.L1166= | Splice Region (SNP) | VAF 9/23 reads (39%) | catalogued as rs377767119, COSV59877710; called by muse, mutect2, varscan2
- ITGAD | c.2312A>G p.D771G | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV66758050; called by muse, mutect2, varscan2
- ITPR1 | c.2314G>A p.E772K (on ENST00000354582; = p.E757K on NM_002222.7) | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.071); catalogued as rs764889284, COSV56981813; called by muse, mutect2, varscan2
- ITPR1 | c.3735C>A p.F1245L (on ENST00000354582; = p.F1230L on NM_002222.7) | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56981846; called by muse, mutect2, varscan2
- ITPR1 | c.6124G>T p.E2042* (on ENST00000354582; = p.E1987* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 77/153 reads (50%) | catalogued as COSV56977346, COSV56981874; called by muse, mutect2, varscan2
- ITSN2 | c.4642G>A p.D1548N | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs370396104; called by muse, mutect2, varscan2
- JAG1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs564566567, COSV54757001; called by muse, mutect2, varscan2
- JPH1 | c.909G>T p.K303N | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60611053; called by muse, mutect2, varscan2
- KAT2B | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as COSV55429453, COSV99770031; called by muse, mutect2, varscan2
- KAT2B | c.1622+2T>C p.X541_splice | Splice Site (SNP) | VAF 23/62 reads (37%) | catalogued as COSV55429466; called by muse, mutect2, varscan2
- KATNAL2 | c.829C>T p.P277S (on ENST00000356157 / NM_001353899.1; = p.P205S on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/253 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55299280; called by muse, mutect2, varscan2
- KCNA6 | c.1517G>A p.R506Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1400476551, COSV54977723; called by muse, mutect2
- KCND2 | c.1155T>G p.I385M | Missense Mutation (SNP) | VAF 109/226 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV58580375; called by muse, mutect2, varscan2
- KCNH5 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 81/169 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.777); catalogued as rs372872099; called by muse, mutect2, varscan2
- KCNH7 | c.470T>G p.F157C | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV59796631; called by muse, mutect2, varscan2
- KCTD16 | c.701A>G p.E234G | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV72578820; called by muse, mutect2, varscan2
- KIAA1109 | c.3839C>G p.P1280R | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV52673393; called by muse, mutect2, varscan2
- KIAA1109 | c.12473C>T p.S4158F | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52673402; called by muse, mutect2, varscan2
- KIAA1210 | c.4411G>T p.D1471Y | Missense Mutation (SNP) | VAF 55/155 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV68177254, COSV68177446; called by muse, mutect2, varscan2
- KIAA1217 | c.4472C>A p.S1491Y | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as COSV56816819; called by muse, mutect2, varscan2
- KIAA1328 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 132/338 reads (39%) | catalogued as COSV54454037; called by muse, mutect2, varscan2
- KIF13B | c.3235G>A p.D1079N | Missense Mutation (SNP) | VAF 78/208 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV101580730; called by muse, mutect2
- KIF13B | c.1647G>T p.K549N | Missense Mutation (SNP) | VAF 104/228 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.039); catalogued as rs769614957, COSV73054419; called by muse, mutect2, varscan2
- KIF27 | c.3697C>T p.R1233W | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1317446725, COSV52827359; called by muse, mutect2
- KIF2B | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.642); catalogued as rs756074198, COSV52130086; called by muse, mutect2, varscan2
- KIF5A | c.1631G>A p.R544Q | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs778864713, COSV54054630; called by muse, varscan2
- KIF5A | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs199608047, COSV54052333; called by muse, varscan2
- KIF5C | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1439125187, COSV69170795; called by muse, mutect2, varscan2
- KLHL1 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 69/175 reads (39%) | catalogued as rs1320029799, COSV64767628; called by muse, mutect2, varscan2
- KLHL4 | c.1537C>T p.R513W | Missense Mutation (SNP) | VAF 105/222 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764922529, COSV64142469; called by muse, mutect2, varscan2
- KPNA5 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 118/290 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs375939202; called by muse, varscan2
- KPNA5 | c.1348A>C p.N450H | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62652495; called by muse, mutect2, varscan2
- KPRP | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.037); catalogued as rs1222199078, COSV64222761; called by muse, mutect2
- KRAS | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 199/491 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs758575947, COSV55724297; called by muse, mutect2, varscan2
- KRT10 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 86/197 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779748369, COSV54089279; called by muse, mutect2, varscan2
- KRT32 | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV56786668; called by muse, varscan2
- KRT35 | c.712-1G>T p.X238_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99877821; called by muse, mutect2
- KRT76 | c.76G>A p.G26S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs753112981, COSV100196129, COSV60118969; called by muse, mutect2, varscan2
- KRTAP24-1 | c.707G>A p.S236N | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV61089487; called by muse, mutect2, varscan2
- KRTAP5-5 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV68784940; called by muse, varscan2
- LACTB | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 11/131 reads (8%) | catalogued as COSV99978977; called by muse, mutect2
- LAMA1 | c.5371G>T p.E1791* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | catalogued as COSV67537117; called by muse, mutect2, varscan2
- LAMA2 | c.7066C>T p.R2356C | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747217321, COSV70347412; called by muse, mutect2, varscan2
- LAMA4 | c.3755C>A p.S1252Y (on ENST00000230538 / NM_001105206.3; = p.S1245Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/253 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1554330310, COSV57897235; called by muse, mutect2, varscan2
- LAMC1 | c.1307C>A p.S436Y | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1388815568, COSV51138336, COSV51142182; called by muse, mutect2, varscan2
- LEF1 | c.972A>T p.K324N | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54467402; called by muse, mutect2, varscan2
- LHCGR | c.2021C>T p.S674F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs1166284442, COSV54297113; called by muse, mutect2, varscan2
- LHCGR | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 96/207 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1304542605, COSV54297127; called by muse, mutect2, varscan2
- LHX4 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.067); catalogued as rs375216188, COSV99761669; called by muse, mutect2
- LIMCH1 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 106/229 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs557978812, COSV58280717; called by muse, varscan2
- LIPF | c.477G>T p.K159N | Missense Mutation (SNP) | VAF 76/187 reads (41%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as COSV53283982; called by muse, mutect2, varscan2
- LMBRD1 | c.1622C>T p.S541L (on ENST00000649011; = p.S519L on NM_018368.4) | Missense Mutation (SNP) | VAF 142/305 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373481039, COSV65298590; called by muse, mutect2, varscan2
- LMBRD2 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99682967; called by muse, mutect2
- LNPEP | c.475A>T p.K159* | Nonsense Mutation (SNP) | VAF 48/98 reads (49%) | catalogued as COSV51478016; called by muse, mutect2, varscan2
- LONRF2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.306); catalogued as COSV66540625; called by muse, mutect2, varscan2
- LRBA | c.590T>C p.M197T | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV63955634; called by muse, mutect2, varscan2
- LRCH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 149/316 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1470042897, COSV57747909; called by muse, mutect2, varscan2
- LRCH3 | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58390183; called by muse, mutect2, varscan2
- LRP1B | c.4729C>A p.L1577I | Missense Mutation (SNP) | VAF 86/169 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as COSV67197912, COSV67221199; called by muse, mutect2, varscan2
- LRP2 | c.7841G>T p.R2614I | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV55553584, COSV55556476; called by muse, mutect2, varscan2
- LRP2 | c.5737C>A p.L1913I | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as COSV55552253; called by muse, mutect2, varscan2
- LRP4 | c.2870G>A p.R957H | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as rs374161249; called by muse, mutect2, varscan2
- LRRC14B | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs199886519, COSV57256856; called by muse, mutect2, varscan2
- LRRC49 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as rs1302585053, COSV53007562; called by muse, mutect2
- LRRK2 | c.3804A>C p.E1268D | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV54150847, COSV54153579; called by muse, mutect2, varscan2
- LRRN4 | c.983G>T p.R328I | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV66644413, COSV66644736, COSV66645863; called by muse, mutect2, varscan2
- LTF | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51608095; called by muse, mutect2, varscan2
- LTK | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV55490664; called by muse, mutect2, varscan2
- LYST | c.9853G>T p.E3285* | Nonsense Mutation (SNP) | VAF 45/104 reads (43%) | catalogued as COSV67707060; called by muse, mutect2, varscan2
- LYST | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); catalogued as COSV67707066; called by muse, mutect2, varscan2
- MAB21L1 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as COSV59785079; called by muse, mutect2, varscan2
- MAGEB3 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV100854723, COSV100854793; called by muse, mutect2
- MAGT1 | c.67G>A p.D23N (on ENST00000618282 / NM_001367916.1; = p.D55N on NM_032121.5) | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV63781718; called by muse, mutect2, varscan2
- MAP7D2 | c.1525G>T p.E509* | Nonsense Mutation (SNP) | VAF 120/226 reads (53%) | catalogued as COSV65527429; called by muse, mutect2, varscan2
- MAP7D3 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 144/373 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as COSV60171013; called by muse, mutect2, varscan2
- MARCHF10 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.122); catalogued as rs761485445, COSV60887267; called by muse, mutect2, varscan2
- MARVELD2 | c.1625G>T p.R542I | Missense Mutation (SNP) | VAF 114/242 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV57780351; called by muse, mutect2, varscan2
- MCM4 | c.502-1G>A p.X168_splice | Splice Site (SNP) | VAF 119/307 reads (39%) | catalogued as rs1486547363, COSV50622865, COSV50623433, COSV50632046; called by muse, mutect2, varscan2
- MDC1 | c.4189A>C p.N1397H | Missense Mutation (SNP) | VAF 115/255 reads (45%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV64524630; called by muse, mutect2, varscan2
- MED17 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 137/329 reads (42%) | catalogued as COSV52600995; called by muse, mutect2, varscan2
- MEI1 | c.1549G>T p.E517* | Nonsense Mutation (SNP) | VAF 41/82 reads (50%) | catalogued as COSV55903073; called by muse, mutect2, varscan2
- MEI1 | c.3203G>A p.R1068Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs767987047, COSV55903081; called by muse, mutect2, varscan2
- MEIOC | c.2422C>T p.R808C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779505985, COSV63440157; called by muse, mutect2, varscan2
- MIA2 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 128/388 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs755963772, COSV99697768; called by muse, mutect2
- MIA3 | c.4816C>T p.R1606C | Missense Mutation (SNP) | VAF 137/303 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768376856, COSV60512940; called by muse, mutect2, varscan2
- MID2 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs1460625771, COSV53309397; called by muse, mutect2, varscan2
- MINAR1 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs189062292, COSV59581110; called by muse, mutect2, varscan2
- MKI67 | c.9341G>T p.R3114I | Missense Mutation (SNP) | VAF 134/265 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs192859477, COSV64074396; called by muse, mutect2, varscan2
- MME | c.1914+1G>A p.X638_splice | Splice Site (SNP) | VAF 115/253 reads (45%) | catalogued as rs1003705057, COSV64707481; called by muse, mutect2, varscan2
- MMP19 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs764541674, COSV59451381; called by muse, mutect2, varscan2
- MMP27 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.655); catalogued as COSV52780890; called by muse, mutect2, varscan2
- MMP27 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs558421984, COSV52780898, COSV52781818; called by muse, mutect2, varscan2
- MNDA | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 271/313 reads (87%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs867226822, COSV63740382; called by muse, mutect2, varscan2
- MOV10L1 | c.3235C>A p.L1079I | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as COSV53171494; called by muse, mutect2, varscan2
- MPO | c.936C>A p.F312L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.428); catalogued as COSV56563943; called by muse, mutect2, varscan2
- MRGPRX4 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 112/234 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs866402838, COSV58590557; called by muse, mutect2, varscan2
- MRPS11 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as rs759886427, COSV57915077; called by muse, mutect2, varscan2
- MRPS30 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 102/218 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50181617; called by muse, mutect2, varscan2
- MRPS35 | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 75/150 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV50011467; called by muse, mutect2, varscan2
- MS4A14 | c.1794G>T p.K598N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV55734985; called by muse, varscan2
- MS4A14 | c.1842G>T p.K614N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV55734421, COSV55734999; called by muse, varscan2
- MSL3 | c.235A>C p.N79H | Missense Mutation (SNP) | VAF 70/155 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56493270; called by muse, mutect2, varscan2
- MTCH1 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753484837, COSV65320604; called by muse, mutect2, varscan2
- MTF2 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.444); catalogued as COSV64769436; called by muse, mutect2
- MTFR1 | c.869G>T p.S290I | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV50951685; called by muse, mutect2, varscan2
- MTHFD1 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs767011731, COSV53699285; called by muse, mutect2, varscan2
- MTM1 | c.289G>T p.G97* | Nonsense Mutation (SNP) | VAF 133/323 reads (41%) | catalogued as COSV60335060; called by muse, mutect2, varscan2
- MTMR3 | c.53T>A p.F18Y | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as COSV60304435; called by muse, mutect2, varscan2
- MTMR7 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 74/180 reads (41%) | catalogued as rs1238407176, COSV51664154; called by muse, mutect2, varscan2
- MTPAP | c.265A>C p.N89H | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.235); catalogued as COSV53933094; called by muse, mutect2, varscan2
- MUC16 | c.9115G>T p.E3039* | Nonsense Mutation (SNP) | VAF 65/145 reads (45%) | catalogued as COSV67466528; called by muse, mutect2, varscan2
- MUC2 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.2); catalogued as rs370519187; called by muse, mutect2, varscan2
- MUC7 | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 186/431 reads (43%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.03); catalogued as COSV59217349; called by muse, mutect2, varscan2
- MYBL2 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as rs1399901346, COSV53827698; called by muse, mutect2, varscan2
- MYBPC1 | c.1169G>A p.R390Q (on ENST00000550270 / NM_206820.2; = p.R415Q on NM_002465.4) | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs147400257; called by muse, mutect2, varscan2
- MYH11 | c.3136G>T p.E1046* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV55546619, COSV55553518; called by muse, mutect2, varscan2
- MYLK4 | c.405A>C p.K135N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51141531; called by muse, mutect2, varscan2
- MYO18B | c.6625G>A p.E2209K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as rs545281386, COSV59127218; called by muse, mutect2, varscan2
- MYO5B | c.3076C>A p.L1026I | Missense Mutation (SNP) | VAF 121/269 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV53218852; called by muse, mutect2, varscan2
- MYO9A | c.2842C>T p.R948C | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs766900248, COSV61851132; called by muse, mutect2, varscan2
- MYOF | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.809); catalogued as rs201829735, COSV63704248; called by muse, mutect2, varscan2
- MYT1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1262501301, COSV100114942; called by muse, mutect2, varscan2
- MYT1L | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 61/129 reads (47%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.019); catalogued as rs776657807, COSV67714668; called by muse, mutect2, varscan2
- NAA30 | c.605G>A p.G202D | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV53648641; called by muse, mutect2, varscan2
- NARS1 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV56876899; called by muse, mutect2, varscan2
- NASP | c.2267C>T p.S756L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs749672551, COSV59647101; called by muse, mutect2, varscan2
- NAV3 | c.5741G>A p.R1914H (on ENST00000397909 / NM_001024383.2; = p.R1892H on NM_014903.6) | Missense Mutation (SNP) | VAF 152/333 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs757028730, COSV57080467; called by muse, mutect2, varscan2
- NAV3 | c.6544G>T p.E2182* (on ENST00000397909 / NM_001024383.2; = p.E2160* on NM_014903.6) | Nonsense Mutation (SNP) | VAF 65/147 reads (44%) | catalogued as COSV57063780, COSV57074575; called by muse, mutect2, varscan2
- NBEA | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 60/152 reads (39%) | catalogued as COSV59759501; called by muse, mutect2, varscan2
- NBEA | c.2086C>T p.R696* | Nonsense Mutation (SNP) | VAF 122/274 reads (45%) | catalogued as rs1296627050, COSV59785071; called by muse, mutect2, varscan2
- NCKAP1L | c.3173A>C p.E1058A | Missense Mutation (SNP) | VAF 106/228 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53206900; called by muse, mutect2, varscan2
- NCR1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766273248, COSV52556187; called by muse, mutect2, varscan2
- NCSTN | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs200596888, COSV54187669; called by muse, mutect2, varscan2
- NDNF | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 34/73 reads (47%) | catalogued as COSV65633488; called by muse, mutect2, varscan2
- NDST4 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 136/301 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs374197902; called by muse, mutect2, varscan2
- NEB | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 143/334 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs747225286, COSV51417665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN3 | c.1271G>T p.G424V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); catalogued as rs1236276788, COSV60551356; called by muse, mutect2, varscan2
- NEFL | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55336995; called by muse, mutect2, varscan2
- NFASC | c.358G>A p.A120T (on ENST00000339876 / NM_001378329.1; = p.A114T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771183209, COSV58358391; called by muse, mutect2, varscan2
- NFAT5 | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV63027533; called by muse, mutect2, varscan2
- NFKB2 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 23/66 reads (35%) | catalogued as COSV51872003; called by muse, mutect2, varscan2
- NHSL2 | c.881G>T p.G294V (on ENST00000510661; = p.G660V on NM_001013627.2) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65453468; called by muse, mutect2, varscan2
- NIPSNAP3A | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 93/233 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as rs775081506, COSV66113363; called by muse, mutect2, varscan2
- NKD2 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs749745224, COSV99724197; called by muse, mutect2, varscan2
- NLRC3 | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs769244221, COSV57090899; called by muse, mutect2, varscan2
- NLRP13 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 94/197 reads (48%) | catalogued as rs1158211016, COSV61621253; called by muse, mutect2, varscan2
- NLRP5 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs374536648; called by muse, mutect2, varscan2
- NME1-NME2 | c.805G>T p.E269* (on ENST00000555572; = p.E244* on NM_001018136.3) | Nonsense Mutation (SNP) | VAF 89/215 reads (41%) | catalogued as rs1400527392, COSV64510407; called by muse, mutect2, varscan2
- NNMT | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.039); catalogued as rs375954126, COSV55473798; called by muse, mutect2, varscan2
- NOSTRIN | c.1208C>T p.S403F (on ENST00000317647 / NM_001039724.4; = p.S325F on NM_052946.3) | Missense Mutation (SNP) | VAF 70/159 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV58321489; called by muse, mutect2, varscan2
- NPY4R | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs781880034, COSV65398097; called by muse, mutect2, varscan2
- NPY5R | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 112/227 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs768685790, COSV58452026, COSV58453583; called by muse, mutect2, varscan2
- NRG1 | c.1624G>A p.A542T (on ENST00000405005 / NM_013964.5; = p.A547T on NM_013956.5) | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs776391266, COSV55154820; called by muse, mutect2, varscan2
- NRIP1 | c.323T>G p.L108* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | catalogued as COSV100012817; called by muse, mutect2
- NRXN2 | c.3490C>T p.R1164C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs868859150, COSV55453435; called by muse, mutect2, varscan2
- NRXN2 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780408, COSV55453455; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSMF | c.592A>G p.K198E | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); catalogued as COSV52998932; called by muse, mutect2, varscan2
- NT5DC3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 103/210 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67321787; called by muse, mutect2, varscan2
- NUCB1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375589971; called by muse, mutect2, varscan2
- NUP54 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 85/187 reads (45%) | catalogued as COSV53575626; called by muse, mutect2, varscan2
- NYAP2 | c.1726A>G p.K576E | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs1484309106, COSV56005206; called by muse, mutect2, varscan2
- OBSCN | c.20091C>A p.F6697L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs774584648, COSV62382847, COSV62921208; called by muse, mutect2, varscan2
- OLFML1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs778517137, COSV61402668; called by muse, mutect2, varscan2
- OPN5 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.818); catalogued as COSV55245576; called by muse, mutect2, varscan2
- OPRPN | c.466A>C p.N156H | Missense Mutation (SNP) | VAF 302/645 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.534); catalogued as COSV68192901; called by muse, mutect2, varscan2
- OPTN | c.710T>C p.L237P | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53810877; called by muse, mutect2, varscan2
- OR13C4 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52926670; called by muse, mutect2, varscan2
- OR14C36 | c.481A>G p.T161A | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV58601289; called by muse, varscan2
- OR14C36 | c.525C>A p.F175L | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV58600536; called by muse, varscan2
- OR1F1 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 78/162 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.58); catalogued as COSV58961053; called by muse, mutect2, varscan2
- OR2L2 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 10/329 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV100823945; called by muse, mutect2
- OR2T1 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 102/310 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs1237913817, COSV63541944, COSV63542681; called by muse, mutect2, varscan2
- OR2W3 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV64456903, COSV64458169; called by muse, mutect2, varscan2
- OR4F4 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 297/383 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs757572005, COSV58220128; called by muse, mutect2, varscan2
- OR4L1 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV59849790; called by muse, mutect2, varscan2
- OR51G1 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV58969228; called by muse, varscan2
- OR52D1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 86/146 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV59487561; called by muse, mutect2, varscan2
- OR56A4 | c.1078A>C p.N360H | Missense Mutation (SNP) | VAF 116/222 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as COSV58110243; called by muse, mutect2, varscan2
- OR5AS1 | c.920G>A p.R307K | Missense Mutation (SNP) | VAF 56/124 reads (45%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV57981806; called by muse, mutect2, varscan2
- OR6C3 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 138/289 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV65571153; called by muse, mutect2, varscan2
- OR6C65 | c.762T>G p.I254M | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.949); catalogued as COSV65568616; called by muse, mutect2, varscan2
- OR6C74 | c.639T>G p.I213M | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.163); catalogued as rs773205169, COSV100667839, COSV59606482; called by muse, mutect2, varscan2
- OR6C75 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.07); catalogued as rs962726938, COSV58551989, COSV58552239; called by muse, mutect2, varscan2
- OR7D2 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 92/180 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.097); catalogued as COSV60139158, COSV60139861; called by muse, mutect2, varscan2
- OR8S1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs140344146; called by muse, mutect2, varscan2
- OR9G4 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 200/457 reads (44%) | catalogued as rs1440620937, COSV57248582; called by muse, mutect2, varscan2
- OSBPL6 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.65); PolyPhen benign (0.103); catalogued as rs377158599; called by muse, mutect2, varscan2
- OTUD5 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV50233946; called by muse, mutect2, varscan2
- OTULINL | c.1010A>G p.D337G | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.157); catalogued as COSV57034527; called by muse, mutect2, varscan2
- P2RY10 | c.308G>T p.R103I | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.361); catalogued as COSV50681389; called by muse, mutect2, varscan2
- P2RY14 | c.326T>G p.I109S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56379218; called by muse, mutect2, varscan2
- PADI4 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs748533338, COSV100966855; called by muse, mutect2
- PAOX | c.966A>C p.K322N | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53372414; called by muse, mutect2, varscan2
- PARP15 | c.1088T>C p.I363T (on ENST00000464300 / NM_001113523.3; = p.I129T on NM_152615.2) | Missense Mutation (SNP) | VAF 74/161 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59972729; called by muse, mutect2, varscan2
- PATJ | c.3580A>G p.T1194A | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV57162418; called by muse, mutect2, varscan2
- PAXIP1 | c.300dup p.G101Wfs*12 | Frame Shift Ins (INS) | VAF 57/135 reads (42%) | catalogued as rs753190856; called by mutect2, varscan2
- PBK | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421906620, COSV57272782; called by muse, mutect2, varscan2
- PCDH19 | c.382A>G p.S128G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs762647337, COSV55263075; called by muse, mutect2, varscan2
- PCDHA11 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs781996593, COSV56502100; called by muse, mutect2, varscan2
- PCDHA13 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.282); catalogued as rs781811851, COSV56480759; called by muse, mutect2, varscan2
- PCDHA6 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.014); catalogued as COSV65350771; called by muse, mutect2, varscan2
- PCDHAC1 | c.2227G>T p.D743Y | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV53849857; called by muse, mutect2, varscan2
- PCDHGA1 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.298); catalogued as rs776876444, COSV65294776, COSV65296622; called by muse, mutect2
- PCDHGA4 | c.2388G>T p.K796N | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV53949406; called by muse, mutect2, varscan2
- PCDHGC3 | c.1212G>T p.K404N | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.089); catalogued as COSV52752374; called by muse, mutect2, varscan2
- PCLO | c.13679G>A p.G4560E | Missense Mutation (SNP) | VAF 77/177 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61635616; called by muse, mutect2, varscan2
- PCNT | c.5178G>T p.E1726D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as COSV64028317; called by muse, mutect2, varscan2
- PCYOX1L | c.182G>A p.G61E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as COSV51002716; called by muse, mutect2, varscan2
- PDE1C | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as rs773228744, COSV100372471, COSV58504631; called by muse, mutect2, varscan2
- PDS5A | c.568T>G p.L190V | Missense Mutation (SNP) | VAF 76/153 reads (50%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.925); catalogued as COSV57825908; called by muse, mutect2, varscan2
- PDZD11 | c.397C>T p.R133C | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.412); catalogued as COSV52103808; called by muse, mutect2, varscan2
- PGAP1 | c.151A>C p.I51L | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as COSV61326241; called by muse, mutect2, varscan2
- PGBD1 | c.2240C>T p.S747L | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs147237521; called by muse, mutect2, varscan2
- PGBD4 | c.1235G>T p.G412V | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV56627824; called by muse, mutect2, varscan2
- PGF | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs751046183, COSV53125488; called by muse, mutect2, varscan2
- PGM2L1 | c.1142A>G p.N381S | Missense Mutation (SNP) | VAF 147/326 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as rs758240888, COSV53346915; called by muse, mutect2, varscan2
- PHTF2 | c.196G>A p.E66K (on ENST00000248550 / NM_001366089.1; = p.E32K on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV50326719; called by muse, mutect2, varscan2
- PI4K2B | c.1169A>G p.N390S | Missense Mutation (SNP) | VAF 90/189 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV53511395; called by muse, mutect2, varscan2
- PI4KB | c.1455C>A p.F485L (on ENST00000368873 / NM_001369623.1; = p.F497L on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/90 reads (43%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as COSV55017507; called by muse, mutect2, varscan2
- PIGV | c.373T>G p.L125V | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV50291742; called by muse, mutect2, varscan2
- PIK3C2A | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV56402935; called by muse, mutect2, varscan2
- PIK3R3 | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 205/469 reads (44%) | catalogued as rs1287980956, COSV53106842; called by muse, mutect2, varscan2
- PIK3R3 | c.340A>C p.K114Q | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.391); catalogued as COSV99422372; called by muse, mutect2
- PIKFYVE | c.1469-1G>T p.X490_splice | Splice Site (SNP) | VAF 59/151 reads (39%) | catalogued as COSV52241189; called by muse, mutect2, varscan2
- PKD2L2 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 176/410 reads (43%) | catalogued as COSV51797335, COSV99296195; called by muse, mutect2, varscan2
- PLCE1 | c.5888A>G p.Y1963C | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53350844; called by muse, mutect2, varscan2
- PLCL1 | c.976A>C p.N326H | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs756609742, COSV70832647; called by muse, varscan2
- PLCL1 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357149217, COSV70821581; called by muse, varscan2
- PLD6 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 74/146 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as rs368055624; called by muse, mutect2, varscan2
- PLEKHA1 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV64569516, COSV64570553; called by muse, mutect2, varscan2
- PLEKHG7 | c.1870+1G>A p.X624_splice | Splice Site (SNP) | VAF 126/272 reads (46%) | catalogued as rs1481905392, COSV60821726; called by muse, mutect2, varscan2
- PLG | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 75/158 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.592); catalogued as rs141045811, COSV51983039; called by muse, mutect2, varscan2
- PLPP1 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 117/283 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.232); catalogued as COSV53305184; called by muse, mutect2, varscan2
- PMPCA | c.696G>T p.K232N | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.098); catalogued as COSV100867786; called by muse, mutect2
- PNISR | c.2011C>T p.R671* | Nonsense Mutation (SNP) | VAF 276/651 reads (42%) | catalogued as COSV65079510; called by muse, mutect2, varscan2
- PNO1 | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 124/352 reads (35%) | catalogued as COSV99718364; called by muse, mutect2
- PNPLA1 | c.1319G>A p.R440Q (on ENST00000394571 / NM_001374623.1; = p.R345Q on NM_173676.2) | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs144648025; called by muse, mutect2, varscan2
- PNPT1 | c.1343T>G p.L448R | Missense Mutation (SNP) | VAF 163/365 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV53177352; called by muse, mutect2, varscan2
- POLA1 | c.3935A>C p.N1312T | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV66886375; called by muse, mutect2, varscan2
- POU3F4 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1354177998, COSV64537973; called by muse, mutect2, varscan2
- PPIG | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 132/274 reads (48%) | catalogued as rs1558904194, COSV53643187; called by muse, mutect2, varscan2
- PPIL4 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV53567205, COSV53568486; called by muse, mutect2, varscan2
- PPM1N | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as COSV55594106; called by muse, mutect2, varscan2
- PPP1R3A | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs4304271, COSV52885444, COSV99492940, COSV99493260; called by muse, mutect2, varscan2
- PPP1R9A | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56880421; called by muse, mutect2, varscan2
- PPP2R5C | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 132/261 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1472722702, COSV58271434; called by muse, mutect2, varscan2
- PPP2R5C | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 193/428 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58271460; called by muse, mutect2, varscan2
- PPP4R1 | c.158A>C p.K53T (on ENST00000400556 / NM_001042388.3; = p.K36T on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53281821; called by muse, mutect2, varscan2
- PPP4R2 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs780289621, COSV55595378; called by muse, mutect2, varscan2
- PPP4R4 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 79/171 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs115996327, COSV100428753; called by muse, mutect2, varscan2
- PRDM9 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1329112975, COSV57003893, COSV57006438; called by muse, mutect2, varscan2
- PREP | c.358T>C p.F120L (on ENST00000369110; = p.F186L on NM_002726.5) | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64870185; called by muse, mutect2, varscan2
- PRF1 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs754602851, COSV64614624; called by muse, mutect2, varscan2
- PRKD3 | c.1490T>C p.V497A | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52213502; called by muse, mutect2, varscan2
- PROX2 | c.590G>T p.S197I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV101507814; called by muse, mutect2
- PRPS1 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100978871; called by muse, mutect2
- PRRC2B | c.3132G>A p.M1044I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs760146261, COSV61935330, COSV61937144; called by muse, mutect2, varscan2
- PRXL2A | c.420C>A p.F140L | Missense Mutation (SNP) | VAF 76/181 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV64690625; called by muse, mutect2, varscan2
- PSG9 | c.1133A>C p.K378T | Missense Mutation (SNP) | VAF 169/396 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.314); catalogued as COSV52485106; called by muse, mutect2, varscan2
- PSMA2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 75/177 reads (42%) | catalogued as COSV55031291; called by muse, mutect2, varscan2
- PTCHD1 | c.1644C>A p.Y548* | Nonsense Mutation (SNP) | VAF 4/90 reads (4%) | catalogued as COSV101037797; called by muse, mutect2
- PTEN | c.431A>C p.K144T | Missense Mutation (SNP) | VAF 71/164 reads (43%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.636); catalogued as COSV64295211, COSV64310658; called by muse, varscan2
- PTPDC1 | c.1677C>A p.F559L (on ENST00000375360 / NM_177995.3; = p.F611L on NM_152422.4) | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56623252; called by muse, mutect2, varscan2
- PTPN20 | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as rs1407423328; called by mutect2, varscan2
- PTPN4 | c.954G>T p.K318N | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0.412); catalogued as COSV55301672; called by muse, mutect2, varscan2
- PTPRB | c.1586G>A p.R529Q | Missense Mutation (SNP) | VAF 79/182 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs184275696, COSV54232350, COSV99715331; called by muse, mutect2, varscan2
- PTPRJ | c.3553A>G p.K1185E | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.92); PolyPhen benign (0.021); catalogued as rs1006913200, COSV69252312; called by muse, mutect2, varscan2
- PUM2 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.84); catalogued as rs763171715, COSV57580741; called by muse, mutect2, varscan2
- PXN | c.1357G>A p.E453K (on ENST00000228307 / NM_001080855.3; = p.E419K on NM_002859.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs964600835, COSV99936024; called by muse, mutect2, varscan2
- PYGL | c.1559C>T p.T520M | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as rs536165697, COSV53586001; called by muse, mutect2, varscan2
- PYROXD1 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 66/140 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53709633; called by muse, mutect2, varscan2
- PZP | c.2213G>A p.R738Q | Missense Mutation (SNP) | VAF 88/189 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs374726093; called by muse, mutect2, varscan2
- PZP | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774449645, COSV54356829; called by muse, mutect2, varscan2
- QRFPR | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as rs189743021, COSV57676742; called by muse, mutect2, varscan2
- QSER1 | c.1180T>G p.Y394D (on ENST00000399302; = p.Y523D on NM_001076786.3) | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV67900605; called by muse, mutect2, varscan2
- RAB41 | c.123C>T p.S41= | Splice Region (SNP) | VAF 101/207 reads (49%) | catalogued as rs780258439, COSV52103984; called by muse, mutect2, varscan2
- RAI14 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774736280, COSV54294768; called by muse, mutect2, varscan2
- RANBP6 | c.1863A>C p.K621N | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52389486; called by muse, mutect2, varscan2
- RAPGEF2 | c.1022T>C p.F341S | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52428281; called by muse, mutect2, varscan2
- RAPGEF2 | c.3640T>G p.L1214V | Missense Mutation (SNP) | VAF 46/78 reads (59%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as COSV52428293; called by muse, mutect2, varscan2
- RASA1 | c.2634G>T p.Q878H | Missense Mutation (SNP) | VAF 135/289 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57193811, COSV57195476; called by muse, mutect2, varscan2
- RASGRF2 | c.2933A>G p.D978G | Missense Mutation (SNP) | VAF 28/498 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.612); catalogued as COSV99429611; called by muse, mutect2
- RASGRP4 | c.1912C>T p.R638C | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs758058477, COSV53038879; called by muse, mutect2, varscan2
- RASSF2 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs369987339; called by muse, mutect2, varscan2
- RB1 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 74/163 reads (45%) | catalogued as CM040262, COSV57296760; called by muse, mutect2, varscan2
- RBAK | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1357803073, COSV62331488; called by muse, mutect2, varscan2
- RCN1 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 67/151 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV50014572; called by muse, mutect2, varscan2
- RDX | c.1016G>T p.R339I | Missense Mutation (SNP) | VAF 325/745 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV58193839; called by muse, mutect2, varscan2
- RELN | c.4726C>T p.R1576* | Nonsense Mutation (SNP) | VAF 32/83 reads (39%) | catalogued as COSV58987651; called by muse, mutect2, varscan2
- REXO5 | c.960+2T>C p.X320_splice | Splice Site (SNP) | VAF 47/113 reads (42%) | catalogued as COSV54472080; called by muse, mutect2, varscan2
- RFPL1 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 103/228 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs745694965, COSV100585671, COSV62977542; called by muse, mutect2, varscan2
- RFPL3 | c.148C>A p.P50T (on ENST00000249007 / NM_001098535.1; = p.P21T on NM_006604.2) | Missense Mutation (SNP) | VAF 78/196 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99967145; called by muse, mutect2, varscan2
- RFX6 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as COSV60585048, COSV60588415; called by muse, mutect2, varscan2
- RGPD2 | c.4213C>T p.P1405S | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.111); catalogued as COSV100553052; called by mutect2, varscan2
- RHEX | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 90/197 reads (46%) | catalogued as COSV58980462, COSV58981114; called by muse, mutect2, varscan2
- RHOXF2B | c.524A>C p.E175A | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV65054848; called by mutect2, varscan2
- RIF1 | c.7028C>A p.T2343N | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV99690739; called by muse, mutect2, varscan2
- RIMS1 | c.3713C>T p.A1238V | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs764984137, COSV53456477; called by muse, mutect2, varscan2
- RIOX2 | c.1357G>A p.V453I (on ENST00000333396 / NM_001042533.2; = p.V452I on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV51712009; called by muse, mutect2, varscan2
- RNASE6 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1269134972, COSV58977495; called by muse, mutect2, varscan2
- RNF139 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52679192; called by muse, mutect2, varscan2
- RNF148 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs200865337; called by muse, mutect2, varscan2
- RNF157 | c.1103C>A p.S368Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs750245340, COSV53944225; called by muse, mutect2, varscan2
- RNF17 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.177); catalogued as COSV55040648; called by muse, mutect2, varscan2
- RNPS1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as COSV57046719; called by muse, mutect2, varscan2
- RP1L1 | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 45/516 reads (9%) | catalogued as rs778117952, COSV101222855, COSV101223347; called by muse, mutect2
- RPL10L | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1264270481, COSV53558575; called by muse, mutect2, varscan2
- RSF1 | c.550G>T p.D184Y | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57840003; called by muse, mutect2, varscan2
- RSPO3 | c.481A>G p.K161E | Missense Mutation (SNP) | VAF 99/196 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV63149389; called by muse, mutect2, varscan2
- RTN4 | c.1634A>C p.N545T | Missense Mutation (SNP) | VAF 128/284 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV58267938; called by muse, mutect2, varscan2
- RXFP3 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.362); catalogued as COSV57505645; called by muse, mutect2, varscan2
- RYR2 | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1217618479, COSV63686091; called by muse, mutect2, varscan2
- S1PR3 | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63980602; called by muse, mutect2, varscan2
- SAFB2 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 88/200 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs776973053, COSV53040549, COSV53040701; called by muse, mutect2, varscan2
- SAMD3 | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs144249057; called by muse, mutect2, varscan2
- SAMD9 | c.4246C>T p.R1416* | Nonsense Mutation (SNP) | VAF 81/203 reads (40%) | catalogued as COSV66073288; called by muse, mutect2, varscan2
- SASH1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.15); catalogued as rs758197362, COSV66561754; called by muse, mutect2, varscan2
- SATB2 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as rs1489038642, COSV53483870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN10A | c.1424A>C p.K475T | Missense Mutation (SNP) | VAF 113/230 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as COSV71861364; called by muse, mutect2, varscan2
- SCN7A | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.346); catalogued as COSV69271332, COSV69271603; called by muse, mutect2, varscan2
- SCYL2 | c.901C>T p.R301C | Missense Mutation (SNP) | VAF 72/155 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as rs750714487, COSV62567954; called by muse, mutect2, varscan2
- SEC14L4 | c.577C>T p.R193* | Nonsense Mutation (SNP) | VAF 83/178 reads (47%) | catalogued as rs141785416, COSV55400563; called by muse, mutect2, varscan2
- SEC16A | c.3232T>C p.F1078L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV51528271; called by muse, mutect2, varscan2
- SEC24B | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 197/436 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs532212635, COSV54497189; called by muse, mutect2, varscan2
- SEC24B | c.1912G>T p.E638* | Nonsense Mutation (SNP) | VAF 81/199 reads (41%) | catalogued as COSV54499449; called by muse, mutect2, varscan2
- SECISBP2L | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773689714, COSV55933601, COSV55934517; called by muse, mutect2, varscan2
- SEMA6D | c.935T>C p.V312A | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60377487; called by muse, mutect2, varscan2
- SEMG2 | c.145T>G p.F49V | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV65647491; called by muse, mutect2, varscan2
- SENP3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1456411712, COSV53435898; called by muse, mutect2, varscan2
- SERPINA11 | c.987A>C p.Q329H | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV58241940; called by muse, mutect2, varscan2
- SET | c.129A>C p.E43D (on ENST00000372692 / NM_001374326.1; = p.E30D on NM_003011.4) | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.119); catalogued as COSV59002546; called by muse, mutect2, varscan2
- SETD2 | c.5128C>T p.R1710C | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57436933; called by muse, mutect2, varscan2
- SETX | c.3485G>T p.R1162I | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.564); catalogued as COSV56385456; called by muse, mutect2, varscan2
- SGCD | c.565G>T p.E189* (on ENST00000435422 / NM_001128209.2; = p.E190* on NM_000337.5) | Nonsense Mutation (SNP) | VAF 16/166 reads (10%) | catalogued as COSV100550276, COSV61908784; called by muse, mutect2
- SGCG | c.95G>T p.R32I | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54560453; called by muse, mutect2, varscan2
- SGO1 | c.887G>T p.R296I | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV55423776; called by muse, mutect2, varscan2
- SHCBP1 | c.1512C>G p.D504E | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as COSV57647620; called by muse, mutect2, varscan2
- SHTN1 | c.1316C>T p.S439L | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs772447430, COSV53380035; called by muse, mutect2, varscan2
- SI | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 112/214 reads (52%) | catalogued as COSV52278991; called by muse, mutect2, varscan2
- SI | c.1263A>C p.K421N | Missense Mutation (SNP) | VAF 112/241 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52279002; called by muse, mutect2, varscan2
- SIGLEC6 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as rs772851483, COSV58433344, COSV58434251; called by muse, mutect2, varscan2
- SIGLEC8 | c.369C>A p.F123L | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV58473016, COSV58473360; called by muse, mutect2, varscan2
- SKA2 | c.163T>C p.S55P | Missense Mutation (SNP) | VAF 142/296 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); catalogued as COSV57521681; called by muse, mutect2, varscan2
- SLC12A5 | c.1137G>T p.E379D (on ENST00000454036 / NM_001134771.2; = p.E356D on NM_020708.5) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV54792331, COSV54793871; called by muse, mutect2, varscan2
- SLC15A1 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 144/352 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.531); catalogued as rs372092782, COSV64729878; called by muse, mutect2, varscan2
- SLC1A2 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.923); catalogued as COSV53521480; called by muse, mutect2, varscan2
- SLC1A3 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99467751; called by muse, mutect2
- SLC22A15 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 67/149 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.33); catalogued as rs767790243, COSV65678061; called by muse, mutect2, varscan2
- SLC26A4 | c.1717G>T p.D573Y | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as CM074556, COSV55916705; called by muse, mutect2, varscan2
- SLC30A9 | c.1550A>C p.E517A | Missense Mutation (SNP) | VAF 54/119 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as COSV52553847, COSV52556111; called by muse, mutect2, varscan2
481 further variants in this file (226 protein-altering or splice-affecting, 232 silent, 23 other) are not listed here.
